CCDI case PBBRIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fc280edb-521d-4b68-a382-314006903c0d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.5 years (4,925 days).

Biospecimens (3 samples)
- Sample 0DF3JR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF3JS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DF3K1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
